Surgical pathology report (de-identified scan), TCGA case TCGA-24-1616, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1616-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient Name: .
Address: Service: Accession #:
Location: Taken:
Gender: MRN: Received:
DOB: Hospital #: Reported:
Patient Type:

Physician(s):

TCGA-24-1616

Other Related Clinical Data:

DIAGNOSIS:

UTERUS, TOTAL ABDOMINAL HYSTERECTOMY

- METASTATIC ADENOCARCINOMA INVOLVING SEROSA AND SUB ENDOMETRIAL MYOMETRIUM
- ENDOMETRIAL POLYPS
- INTRAMURAL LEIOMYOMA
- CERVIX WITH NO HISTOPATHOLOGIC ABNORMALITY

OVARY, LEFT, SALPINGO-OOPHORECTOMY

- PAPILLARY SEROUS ADENOCARCINOMA, MODERATELY DIFFERENTIATED (FIGO GRADE II/III), INVOLVING PERI-OVARIAN SOFT TISSUE

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY

- METASTATIC ADENOCARCINOMA, INVOLVING TUBAL EPITHELIUM AND PARATUBAL SOFT TISSUE

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- METASTATIC ADENOCARCINOMA, INVOLVING OVARIAN PARENCHYMA AND PERI-OVARIAN SOFT TISSUE

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- METASTATIC ADENOCARCINOMA, INVOLVING PERITUBAL SOFT TISSUE

SOFT TISSUE, "LARGE BOWEL TUMOR," EXCISION

- METASTATIC ADENOCARCINOMA

OMENTUM, EXCISION

- METASTATIC ADENOCARCINOMA
- ONE LYMPH NODE WITH NO EVIDENCE OF MALIGNANCY

personal

By this signature, I attest that the above diagnosis is based upon my

examination of the slides (and/or other material indicated in the diagnosis).

[page 2 of 3]
is smooth, but there is a solid area with exophytic, tan, polypoid tumor. Attached to the external surface of the mass is soft tissue measuring 3.0 x 1.5 x 1.5 cm, but cut surfaces do not show any identifiable fallopian tube. Also present in the container is a cassette labeled "FS2" that holds a piece of tumor measuring 2.0 x 1.5 x 0.3 cm. Labeled B1 - FS2 remnant; B2 and B3 - tumor present on inked ovarian surface; B4 to B5 - tumor; B6 - necrotic tumor; B7 - tumor nodule within cyst; B8 to B9 - attached soft tissue (possible fallopian tube). B10-B14: additional tumor.

The third container is labeled "#3, right adnexa" and contains a single piece of tan, friable, partially necrotic tumor measuring 8.5 x 7.3 x 4.0 cm. One surface is smooth and white, suggesting the possibility that someone opened the specimen prior to receipt in pathology. A portion of fallopian tube measuring 2.6 cm in length and 0.5 cm in diameter includes fimbria and is adhered to the outer surface of the mass. Although adhered to the mass, the fallopian tube is mobile and does not appear to be involved by the tumor. Labeled C1 to C4 - tumor; C5 - fallopian tube. C6-C10 : additional tumor.

The fourth container is labeled "#4, omentum" and contains two pieces of lymphoid tissue together measuring 16 x 14 x 2 cm. Approximately one-fourth of the tissue is involved by a firm white tumor, the largest single implant measuring 9.5 cm in maximum dimension. The specimen is sectioned at 0.3-0.4 cm intervals and every tumor nodule is sampled at least once. All the tumor implants have a similar gross appearance. Labeled D1 to D13.

Synopsis:

SYNOPTIC-REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT.
2. The HISTOLOGIC DIAGNOSIS is:
- Serous adenocarcinoma in ovaries
- Poorly-differentiated carcinoma in omentum
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
- Right and left ovary (synchronous primary tumors)
4. The FIGO GRADE of the tumor is:
- Not applicable
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
- G3 (Poorly-differentiated)
6. Tumor IS identified on both ovarian surfaces.
7. Tumor DOES NOT invade the mesovarium.
8. Tumor DOES NOT invade the adjacent fallopian tube, but is present in the paratubal soft tissue.
9. Tumor invasion of non-adnexal pelvic soft tissue CANNOT BE EVALUATED.
10. Tumor involvement of the non-adnexal pelvic peritoneum CANNOT BE EVALUATED.
11. Metastatic involvement of the EXTRAPELVIC PERITONEUM is PRESENT (omentum).
12. Metastatic involvement of the omentum is PRESENT.
13. The maximum dimension of tumor implants outside the true pelvis is 9.5 cm.
14. Metastatic involvement of the uterine serosa CANNOT BE EVALUATED.
15. Metastatic involvement of the endometrium CANNOT BE EVALUATED.
16. Regional lymph node metastases are present.
17. The total number of regional lymph nodes examined is 1.
18. The total number of metastatically-involved regional lymph nodes is 1.
19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition
T3c	IIIC	Peritoneal metastasis beyond true pelvis measuring > 2 cm in greatest dimension or regional lymph node metastasis

[page 3 of 3]
diffusely infiltrate/involved by numerous tan-grey, separate or confluent nodular lesions with areas of necrosis and hemorrhage.

Synopsis

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT
2. The HISTOLOGIC DIAGNOSIS is:
Serous adenocarcinoma
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Left and right ovary
4. The FIGO GRADE of the tumor is:
II
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3
6. Tumor IS identified on the ovarian surface(s).
7. Tumor DOES invade the mesovarium.
8. Tumor DOES invade the adjacent fallopian tube.
9. Tumor DOES invade the pelvic soft tissue.
10. Tumor involvement of the pelvic peritoneum CANNOT BE EVALUATED.
11. Metastatic involvement of the EXTRAPELVIC peritoneum CANNOT BE EVALUATED.
12. Metastatic involvement of the omentum is PRESENT.
13. The maximum dimension of tumor implants outside the true pelvis is 10 cm.
14. Metastatic involvement of the uterine serosa is PRESENT.
15. Metastatic involvement of the endometrium is PRESENT.
16. Regional lymph node metastases CANNOT BE EVALUATED.
17. The total number of regional lymph nodes examined is 0
18. The total number of metastatically-involved regional lymph nodes CANNOT BE EVALUATED
19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition
T3c	IIIC	Macroscopic peritoneal metastasis beyond true pelvis measuring > 2 cm in greatest dimension,

THE REGIONAL LYMPH NODES are classified as:

NX (Nodal status cannot be assessed)

THE STATUS OF DISTANT TUMOR SITES is classified as:

MX (Status cannot be assessed)

20. The FINAL AJCC/UICC/FIGO STAGE IS:

AJCC/UICC/FIGO

X

Insufficient data to assign stage

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 529aabe8-784d-41f1-b524-2007caeb2452 (TCGA-24-1616.D8C764D9-0FE8-488E-8AA1-DA73A8C10B01.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).